Somatic mutation profile of tumor specimen TCGA-KD-A5QS-01A (aliquot TCGA-KD-A5QS-01A-11D-A27P-09) from TCGA case TCGA-KD-A5QS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Myometrium; Age at diagnosis: 55.9 years (20,410 days).
Specimen TCGA-KD-A5QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ae91d71-ed87-45f5-88a6-52e22b572d51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KD-A5QS-10A (Blood Derived Normal), aliquot TCGA-KD-A5QS-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b9d62d5-15cf-4ec6-9b20-c02ec295c882

The open-access MAF lists 80 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 12, Splice Site 5, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 54/87 reads (62%) | catalogued as rs1554270809, COSV51650022; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.1259A>C p.H420P | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99366094; called by muse, mutect2, varscan2
- ADGRA1 | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 20/29 reads (69%) | catalogued as COSV101192658; called by muse, mutect2, varscan2
- ADORA2A | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100417888, COSV58379905; called by muse, mutect2, varscan2
- AKAP4 | c.2302A>T p.N768Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100654133, COSV100654205; called by muse, mutect2, varscan2
- ANO4 | c.905A>T p.Y302F (on ENST00000392977 / NM_001286615.2; = p.Y267F on NM_178826.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.585); catalogued as COSV100152332; called by muse, mutect2, varscan2
- ANXA1 | c.353T>A p.F118Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV99973852; called by muse, mutect2, varscan2
- ARHGAP27 | c.1859C>G p.P620R (on ENST00000428638 / NM_001282290.1; = p.P279R on NM_199282.3) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV100976471; called by muse, mutect2, varscan2
- ARHGAP32 | c.2889G>C p.E963D (on ENST00000310343 / NM_001378025.1; = p.E614D on NM_014715.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as COSV100087238; called by muse, mutect2, varscan2
- ATP10D | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs1185295382, COSV56711240; called by muse, mutect2, varscan2
- BCL9 | c.4120C>A p.P1374T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99324721; called by muse, mutect2
- BRD3 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.97); catalogued as rs62639321, COSV100324812; called by muse, mutect2, varscan2
- CDK3 | c.195-1G>A p.X65_splice | Splice Site (SNP) | VAF 20/85 reads (24%) | catalogued as COSV100044170; called by muse, mutect2, varscan2
- CEACAM1 | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148191044; called by muse, mutect2, varscan2
- CENPE | c.5728G>A p.E1910K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99477337; called by muse, mutect2, varscan2
- CXorf38 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100010247; called by muse, mutect2, varscan2
- DMD | c.1144C>G p.H382D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920597; called by muse, mutect2, varscan2
- DNAJA4 | c.385C>G p.L129V (on ENST00000343789; = p.L158V on NM_018602.3) | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV100655147; called by muse, mutect2, varscan2
- DNMT3B | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52415243; called by muse, mutect2, varscan2
- EGR2 | c.595T>G p.S199A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99654039; called by muse, mutect2, varscan2
- FAM47C | c.2470C>A p.L824I | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.444); catalogued as COSV63725504; called by muse, mutect2, varscan2
- GNL3L | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV60577866; called by muse, mutect2, varscan2
- GPX5 | c.491del p.G164Afs*11 | Frame Shift Del (DEL) | VAF 75/156 reads (48%) | catalogued as COSV69079329; called by mutect2, pindel, varscan2
- HS3ST3B1 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100714482; called by muse, mutect2, varscan2
- KIAA1549 | c.1783G>T p.V595F | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs1372701744, COSV99650128; called by muse, mutect2, varscan2
- KIF12 | c.1899C>G p.S633R (on ENST00000640217; = p.S495R on NM_138424.1) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV100936067, COSV65117386; called by muse, mutect2, varscan2
- KLHL1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100917096; called by muse, mutect2, varscan2
- KLRC3 | c.497C>G p.A166G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV101122895, COSV67250242; called by muse, mutect2, varscan2
- KNDC1 | c.3817G>C p.V1273L | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV100463830; called by muse, mutect2, varscan2
- KSR1 | c.1229A>T p.D410V (on ENST00000644974 / NM_001367810.1; = p.D273V on NM_014238.2) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99258626; called by muse, mutect2, varscan2
- MCF2 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs781705774, COSV100644588; called by muse, mutect2, varscan2
- MCM10 | c.1939C>G p.P647A (on ENST00000484800 / NM_182751.3; = p.P646A on NM_018518.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV101097998; called by muse, mutect2, varscan2
- MGAT5B | c.2350C>T p.Q784* (on ENST00000569840 / NM_001199172.2; = p.Q782* on NM_144677.3) | Nonsense Mutation (SNP) | VAF 68/134 reads (51%) | catalogued as COSV100047559; called by muse, mutect2, varscan2
- NEUROG3 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99653454; called by muse, mutect2, varscan2
- ODAM | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV101258039; called by muse, mutect2, varscan2
- OLFM3 | c.157C>A p.Q53K (on ENST00000338858 / NM_001288821.1; = p.Q33K on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100129050; called by muse, mutect2
- OR4K2 | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100064247; called by muse, mutect2
- OR5T2 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV57588178; called by muse, mutect2, varscan2
- PAPPA | c.4364T>C p.V1455A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV60282817; called by muse, mutect2, varscan2
- PARN | c.960C>A p.P320= | Splice Region (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100420764; called by muse, mutect2, varscan2
- PARP15 | c.1232-1G>T p.X411_splice (on ENST00000464300 / NM_001113523.3; = p.X177_splice on NM_152615.2) | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100117013; called by muse, mutect2
- PCDHA1 | c.1540A>G p.S514G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100974314; called by muse, mutect2, varscan2
- PCMTD2 | c.484C>A p.R162S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204059; called by muse, varscan2
- PHLPP2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100673572; called by muse, mutect2, varscan2
- PKHD1L1 | c.2779A>T p.I927F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV101005693; called by muse, mutect2
- PPP1R3A | c.2453A>G p.E818G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as COSV99492284; called by muse, mutect2, varscan2
- SEPTIN4 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100400250; called by muse, mutect2, varscan2
- SEPTIN4 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); catalogued as COSV100400252; called by muse, mutect2, varscan2
- SP140 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100613524; called by muse, mutect2, varscan2
- SPHKAP | c.2308A>G p.S770G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100763846; called by muse, mutect2, varscan2
- SPTBN4 | c.2564G>A p.R855H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100150339; called by muse, mutect2, varscan2
- STOML1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs778456277, COSV100381875; called by muse, mutect2, varscan2
- SV2C | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV100455848; called by muse, mutect2, varscan2
- TDG | c.975G>C p.K325N | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV57168380; called by muse, mutect2, varscan2
- TFDP2 | c.192A>G p.I64M (on ENST00000489671 / NM_001178139.2; = p.I3M on NM_006286.5) | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV100050745; called by muse, mutect2, varscan2
- THEMIS | c.167T>A p.V56D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100965287; called by muse, mutect2, varscan2
- TMEM132D | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1281009371, COSV70621057; called by muse, mutect2, varscan2
- TTN | c.64960G>A p.A21654T (on ENST00000591111; = p.A14230T on NM_003319.4) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | PolyPhen benign (0.007); catalogued as rs746519147, COSV60148042, COSV60310419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF423 | c.2424C>G p.I808M (on ENST00000563137 / NM_001379286.1; = p.I800M on NM_015069.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV99280620; called by muse, mutect2, varscan2
- ZNF782 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100001259; called by muse, mutect2, varscan2
- ENAM | c.2583del p.E862Kfs*7 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- LDHB | c.130-6_132del p.X44_splice | Splice Site (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SEC24D | c.1392_1399del p.E464Dfs*25 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.399_409del p.T135Hfs*7 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- SNAP91 | c.1291dup p.T431Nfs*6 | Frame Shift Ins (INS) | VAF 33/82 reads (40%) | called by mutect2, pindel, varscan2
- TTN | c.670-1_670del p.X224_splice | Splice Site (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- TUT7 | c.452_473del p.V151Afs*2 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- ALOX5 | c.1623C>A p.T541= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100980002, COSV100980063; called by muse, mutect2, varscan2
- CGN | c.1458A>G p.V486= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99642045; called by muse, mutect2, varscan2
- KAT2B | c.978A>G p.Q326= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99769019; called by muse, mutect2, varscan2
- KLRC3 | c.498C>G p.A166= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV101122894, COSV67250458; called by muse, mutect2, varscan2
- MAP3K2 | c.1812A>G p.R604= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100789268; called by muse, mutect2, varscan2
- MTTP | c.2550C>A p.G850= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV99644887; called by muse, mutect2, varscan2
- PROKR2 | c.303G>A p.L101= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV54086549, COSV99450616; called by muse, mutect2, varscan2
- RANBP3 | c.1383C>G p.A461= (on ENST00000340578 / NM_007322.3; = p.A456= on NM_003624.3) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as rs377714973; called by muse, mutect2, varscan2
- RYR2 | c.7263C>T p.S2421= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV63682970; called by muse, mutect2, varscan2
- STYXL2 | c.1596C>T p.N532= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99608774, COSV99609074; called by muse, mutect2, varscan2
- TPGS2 | c.273A>T p.G91= | Silent (SNP) | VAF 61/77 reads (79%) | catalogued as COSV100528767; called by muse, mutect2, varscan2
- ZNF782 | c.1398A>T p.I466= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV100001258; called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 6/58 reads (10%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
